Somatic mutation profile of tumor specimen ALCH-B1U4-TTP1-A (aliquot ALCH-B1U4-TTP1-A-2-0-D-A76I-36) from ALCHEMIST case ALCH-B1U4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.8 years (27,319 days).
Specimen ALCH-B1U4-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 853454c7-03c8-43ba-8e1c-eee0b45d937e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1U4-NB1-A (Blood Derived Normal), aliquot ALCH-B1U4-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ae32233-cda8-430f-a46c-8a62160080fd

The open-access MAF lists 27 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 6, 5'UTR 1, Splice Site 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADRB2 | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 29/253 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374596758; called by muse, mutect2, varscan2
- HUWE1 | c.5528G>A p.R1843H | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs727503965, COSV53357328; ClinVar: uncertain significance; called by muse, mutect2
- NDUFA12 | c.70C>A p.L24I | Missense Mutation (SNP) | VAF 34/482 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV59846437; called by muse, mutect2
- PRUNE2 | c.4846C>T p.R1616C | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs750530554, COSV65045488; called by muse, varscan2
- PUS3 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as rs202176811; called by muse, mutect2
- RAI1 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55394371; called by muse, mutect2
- CAT | c.1261C>T p.H421Y | Missense Mutation (SNP) | VAF 19/284 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.216); called by muse, mutect2
- CHRM4 | c.421C>A p.P141T | Missense Mutation (SNP) | VAF 22/456 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.688); called by muse, mutect2
- COLGALT2 | c.1814C>A p.A605D | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2
- FNDC3A | c.2846C>T p.P949L (on ENST00000492622 / NM_001079673.2; = p.P893L on NM_014923.5) | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2
- HAO1 | c.134_135insA p.R46Qfs*14 | Frame Shift Ins (INS) | VAF 7/49 reads (14%) | called by mutect2, varscan2
- JAM2 | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2
- NUMBL | c.26G>A p.G9D | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.086); called by muse, mutect2
- PCK2 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.337); called by muse, mutect2
- PRPF6 | c.2130G>C p.K710N | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- PTPN3 | c.523C>T p.H175Y | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.005); called by muse, mutect2
- SEMA3F | c.336+1G>C p.X112_splice | Splice Site (SNP) | VAF 10/172 reads (6%) | called by muse, mutect2
- THOC2 | c.2450T>A p.L817Q | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZFC3H1 | c.2602A>G p.I868V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.94); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- C8orf34 | c.1053A>T p.P351= | Silent (SNP) | VAF 12/170 reads (7%) | called by muse, mutect2
- CMYA5 | c.669A>T p.G223= | Silent (SNP) | VAF 11/75 reads (15%) | called by muse, mutect2, varscan2
- GATA6 | c.549C>T p.A183= | Silent (SNP) | VAF 15/171 reads (9%) | called by muse, mutect2
- IRX4 | c.648C>T p.D216= | Silent (SNP) | VAF 18/218 reads (8%) | catalogued as rs778606713, COSV51470989; called by muse, mutect2
- MRPL14 | c.21C>T p.L7= | Silent (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- RABAC1 | c.24G>A p.Q8= | Silent (SNP) | VAF 23/330 reads (7%) | called by muse, mutect2
- PSG2 | c.*97C>G | 3'UTR (SNP) | VAF 4/44 reads (9%) | called by mutect2, varscan2
- TTC21A | c.-40G>A | 5'UTR (SNP) | VAF 28/462 reads (6%) | called by muse, mutect2
